Surgical pathology report (de-identified scan), TCGA case TCGA-75-7030, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-75-7030-01A (Primary Tumor).

[page 1 of 5]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details

Sample Number	Sample Type
	BUFFY
	TUMOUR

[page 2 of 5]
					Histology and staging			
Sample Preparation	Site of Tissue	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)
FF	RLL lung			processing		8	20 RESECT	OTH
FF						0	12 RESECT	OTH

[page 3 of 5]
Tumour Size (cm)	Histology	Grade/ Differentiation	Pathologic al T	Pathologic al N	Clinical M	VALCSG Stage
5.9		3 I	T3,NOS	N0	M0	
5.9		3 I	T3,NOS	N0	M0	

[page 4 of 5]
Histology Comments

Site of primary: Right lower lobe lung with posterior segments of upper lobe. Histologic type: Adenocarcinoma,
Site of primary: Right lower lobe lung with posterior segments of upper lobe. Histologic type: Adenocarcinoma,

[page 5 of 5]
Slide URL

[REDACTED]

Source: NCI Genomic Data Commons file ee2b234a-b157-4759-85c4-e8f4c07f3e1a (TCGA-75-7030.34FB09FF-9B3B-4197-8FB7-91FE66981AC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).